Surgical pathology report (de-identified scan), TCGA case TCGA-HT-A5R5, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-A5R5-01A (Primary Tumor).

Pathology Report for

Diagnosis:

Oligodendroglioma, grade II

Microscopic Description:

Tumor cells have consistently round to oval nuclei. Many have perinuclear halos. Atypia is again mild with scattered moderately atypical nuclei. The tumor infiltrates diffusely throughout both the gray and white matter. In the latter, perineuronal satellitosis is prominent. No mitoses are identified and there is no microvascular proliferation nor necrosis.

ICD O-3
Oligodendroglioma 9450/3
Site Path Brain NOS C71.9
CSCF Brain, supratentorial C71.0
JW 2/27/13

2/27/13

Source: NCI Genomic Data Commons file 492abb46-49e6-44b2-a1ab-c7116b001025 (TCGA-HT-A5R5.9A308F04-2E34-40CB-97FC-A3A5D111FA25.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).